CCDI case PBBWNC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/88757c8d-c5ce-4f62-aee7-817c89d1a7cd

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 15.9 years (5,805 days).

Biospecimens (3 samples)
- Sample 0DJG6Z: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJGCR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJGE4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
